Somatic mutation profile of tumor specimen TCGA-SG-A6Z4-01A (aliquot TCGA-SG-A6Z4-01A-22D-A33E-09) from TCGA case TCGA-SG-A6Z4, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 47.6 years (17,368 days).
Specimen TCGA-SG-A6Z4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 842450c0-6331-403d-bc65-97e288a50758.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SG-A6Z4-10A (Blood Derived Normal), aliquot TCGA-SG-A6Z4-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d4dd311-edcb-4b7e-90eb-1105eb4af31e

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Splice Site 2, Nonsense Mutation 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.994-1G>C p.X332_splice | Splice Site (SNP) | VAF 30/35 reads (86%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs766460335, COSV101186604; called by muse, mutect2, varscan2
- ATG5 | c.482G>T p.R161I | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV58348854; called by muse, mutect2, varscan2
- BRINP3 | c.2198A>T p.K733M | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100818316; called by muse, mutect2, varscan2
- CACNA1H | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs774565789, COSV100670763; called by muse, mutect2, varscan2
- CCDC33 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs201603982, COSV100350564; called by muse, mutect2, varscan2
- DACH2 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287413461, COSV100912505; called by muse, mutect2, varscan2
- DCC | c.3397C>T p.R1133W | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs889494004, COSV71440987; called by muse, mutect2, varscan2
- DDX18 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV54310183, COSV99604282; called by muse, mutect2
- GPR50 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs752426790, COSV99505627; called by muse, mutect2, varscan2
- GRIK2 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100023060; called by muse, mutect2, varscan2
- GSE1 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99496022; called by muse, mutect2, varscan2
- HECW1 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.722); catalogued as COSV101222810; called by muse, mutect2, varscan2
- ITGA6 | c.1697A>G p.E566G (on ENST00000442250; = p.E527G on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99905027; called by muse, mutect2, varscan2
- KCNC4 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs200184574, COSV100873564; called by muse, mutect2, varscan2
- KLHL1 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV100916996; called by muse, mutect2, varscan2
- KRT77 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs201690097; called by muse, mutect2, varscan2
- LRRTM4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139560, COSV69139830; called by muse, mutect2, varscan2
- MACF1 | c.1524-1G>T p.X508_splice | Splice Site (SNP) | VAF 29/59 reads (49%) | catalogued as COSV100482439; called by muse, mutect2, varscan2
- MARCHF11 | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV60137456; called by muse, mutect2, varscan2
- MTFMT | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.164); catalogued as COSV99584125; called by muse, mutect2, varscan2
- MTMR12 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99373352; called by muse, mutect2, varscan2
- MYH9 | c.5730G>T p.M1910I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV99337853; called by muse, mutect2, varscan2
- OR10Q1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as COSV57471788; called by muse, mutect2, varscan2
- OTP | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100119684; called by muse, mutect2, varscan2
- PLEKHA7 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.097); catalogued as rs775934808, COSV63044355; called by muse, mutect2, varscan2
- SF3A3 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100885597; called by muse, mutect2, varscan2
- SLC30A8 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101438243; called by muse, mutect2, varscan2
- TNFRSF21 | c.1726T>C p.F576L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759712817, COSV99729096; called by muse, mutect2, varscan2
- ZNF823 | c.1634A>G p.H545R | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV57873492; called by muse, mutect2, varscan2
- AKAP6 | c.837T>C p.A279= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99798259; called by muse, mutect2, varscan2
- ANKMY1 | c.2709C>T p.C903= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1024263396, COSV99801265; called by muse, mutect2, varscan2
- EPAS1 | c.1263C>T p.F421= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs142534349, COSV55385088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HS3ST6 | c.744C>T p.S248= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs767396198, COSV99562546; called by muse, mutect2, varscan2
- PRKCG | c.711G>A p.E237= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs116236420, COSV54735077; called by muse, mutect2, varscan2
- RSPH1 | c.381C>T p.T127= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99370316; called by mutect2, varscan2
- SLCO1B3 | c.840G>A p.P280= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs555631927, COSV53934013; called by muse, mutect2, varscan2
- UGT3A1 | c.630C>T p.F210= | Silent (SNP) | VAF 44/72 reads (61%) | catalogued as COSV57101568, COSV99954281; called by muse, mutect2, varscan2
- CTTN | c.*555G>A | 3'UTR (SNP) | VAF 32/83 reads (39%) | catalogued as rs1168076894, COSV100097127; called by muse, mutect2, varscan2
- DUSP13 | c.*808C>T | 3'UTR (SNP) | VAF 12/22 reads (55%) | catalogued as rs150329504; called by muse, varscan2
